Surgical pathology report (de-identified scan), TCGA case TCGA-F4-6807, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Asterand, specimen TCGA-F4-6807-01A (Primary Tumor).

[page 1 of 2]
[REDACTED]

[REDACTED]	[REDACTED]	Formatted Path Report
------------	------------	-----------------------

[REDACTED]	[REDACTED]	LARGE INTESTINE TISSUE CHECKLIST Specimen type: Colectomy Specimen size: Not specified Tumor site: Colon Tumor size: 9 x 8 x 2 cm Tumor features: None specified Histologic type: Adenocarcinoma Histologic grade: Moderately differentiated Tumor extent: Pericolonic tissues Lymph nodes: 12/12 positive for metastasis (Intraabdominal 12/12) Margins: Uninvolved Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None	[REDACTED]
------------	------------	---	------------

[page 2 of 2]
Date of Procurement

1. **Introduction**

2. **Background**

3. **Methodology**

4. **Results**

5. **Discussion**

6. **Conclusion**

7. **References**

8. **Appendix**

9. **Figure 1**

10. **Figure 2**

11. **Figure 3**

12. **Figure 4**

13. **Figure 5**

14. **Figure 6**

15. **Figure 7**

16. **Figure 8**

17. **Figure 9**

18. **Figure 10**

19. **Figure 11**

20. **Figure 12**

21. **Figure 13**

22. **Figure 14**

23. **Figure 15**

24. **Figure 16**

25. **Figure 17**

26. **Figure 18**

27. **Figure 19**

28. **Figure 20**

29. **Figure 21**

30. **Figure 22**

31. **Figure 23**

32. **Figure 24**

33. **Figure 25**

34. **Figure 26**

35. **Figure 27**

36. **Figure 28**

37. **Figure 29**

38. **Figure 30**

39. **Figure 31**

40. **Figure 32**

41. **Figure 33**

42. **Figure 34**

43. **Figure 35**

44. **Figure 36**

45. **Figure 37**

46. **Figure 38**

47. **Figure 39**

48. **Figure 40**

49. **Figure 41**

50. **Figure 42**

51. **Figure 43**

52. **Figure 44**

53. **Figure 45**

54. **Figure 46**

55. **Figure 47**

56. **Figure 48**

57. **Figure 49**

58. **Figure 50**

59. **Figure 51**

60. **Figure 52**

61. **Figure 53**

62. **Figure 54**

63. **Figure 55**

64. **Figure 56**

65. **Figure 57**

66. **Figure 58**

67. **Figure 59**

68. **Figure 60**

69. **Figure 61**

70. **Figure 62**

71. **Figure 63**

72. **Figure 64**

73. **Figure 65**

74. **Figure 66**

75. **Figure 67**

76. **Figure 68**

77. **Figure 69**

78. **Figure 70**

79. **Figure 71**

80. **Figure 72**

81. **Figure 73**

82. **Figure 74**

83. **Figure 75**

84. **Figure 76**

85. **Figure 77**

86. **Figure 78**

87. **Figure 79**

88. **Figure 80**

89. **Figure 81**

90. **Figure 82**

91. **Figure 83**

92. **Figure 84**

93. **Figure 85**

94. **Figure 86**

95. **Figure 87**

96. **Figure 88**

97. **Figure 89**

98. **Figure 90**

99. **Figure 91**

100. **Figure 92**

101. **Figure 93**

102. **Figure 94**

103. **Figure 95**

104. **Figure 96**

105. **Figure 97**

106. **Figure 98**

107. **Figure 99**

108. **Figure 100**

109. **Figure 101**

110. **Figure 102**

111. **Figure 103**

112. **Figure 104**

113. **Figure 105**

114. **Figure 106**

115. **Figure 107**

116. **Figure 108**

117. **Figure 109**

118. **Figure 110**

119. **Figure 111**

120. **Figure 112**

121. **Figure 113**

122. **Figure 114**

123. **Figure 115**

124. **Figure 116**

125. **Figure 117**

126. **Figure 118**

127. **Figure 119**

128. **Figure 120**

129. **Figure 121**

130. **Figure 122**

131. **Figure 123**

132. **Figure 124**

133. **Figure 125**

134. **Figure 126**

135. **Figure 127**

136. **Figure 128**

137. **Figure 129**

138. **Figure 130**

139. **Figure 131**

140. **Figure 132**

141. **Figure 133**

142. **Figure 134**

143. **Figure 135**

144. **Figure 136**

145. **Figure 137**

146. **Figure 138**

147. **Figure 139**

148. **Figure 140**

149. **Figure 141**

150. **Figure 142**

151. **Figure 143**

152. **Figure 144**

153. **Figure 145**

154. **Figure 146**

155. **Figure 147**

156. **Figure 148**

157. **Figure 149**

158. **Figure 150**

159. **Figure 151**

160. **Figure 152**

161. **Figure 153**

162. **Figure 154**

163. **Figure 155**

164. **Figure 156**

165. **Figure 157**

166. **Figure 158**

167. **Figure 159**

168. **Figure 160**

169. **Figure 161**

170. **Figure 162**

171. **Figure 163**

172. **Figure 164**

173. **Figure 165**

174. **Figure 166**

175. **Figure 167**

176. **Figure 168**

177. **Figure 169**

178. **Figure 170**

179. **Figure 171**

180. **Figure 172**

181. **Figure 173**

182. **Figure 174**

183. **Figure 175**

184. **Figure 176**

185. **Figure 177**

186. **Figure 178**

187. **Figure 179**

188. **Figure 180**

189. **Figure 181**

190. **Figure 182**

191. **Figure 183**

192. **Figure 184**

193. **Figure 185**

194. **Figure 186**

195. **Figure 187**

196. **Figure 188**

197. **Figure 189**

198. **Figure 190**

199. **Figure 191**

200. **Figure 192**

201. **Figure 193**

202. **Figure 194**

203. **Figure 195**

204. **Figure 196**

205. **Figure 197**

206. **Figure 198**

207. **Figure 199**

208. **Figure 200**

209. **Figure 201**

210. **Figure 202**

211. **Figure 203**

212. **Figure 204**

213. **Figure 205**

214. **Figure 206**

215. **Figure 207**

216. **Figure 208**

217. **Figure 209**

218. **Figure 210**

219. **Figure 211**

220. **Figure 212**

221. **Figure 213**

222. **Figure 214**

223. **Figure 215**

224. **Figure 216**

225. **Figure 217**

226. **Figure 218**

227. **Figure 219**

2

Source: NCI Genomic Data Commons file 93eac04c-8047-4b5b-b86a-9553aa039289 (TCGA-F4-6807.F0DE4E3E-4BEE-4AEE-AF8C-37A6DA374814.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).